Surgical pathology report (de-identified scan), TCGA case TCGA-HE-7129, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-7129-01A (Primary Tumor).

[page 1 of 4]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details								Histology ar
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date
	TUMOUR BUFFY	FF FF		RENL RENL				

[page 2 of 4]
nd staging						
Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiat ion	Pathologic al T
	RESECT	Right kidney	14.5	Papillary renal ca., eosinophilic type	X	T2,NOS
	RESECT	Right kidney	14.5	Papillary renal ca., eosinophilic type	X	T2,NOS

[page 3 of 4]
Pathologic al N	Clinical M	Histology Comments	Slide URL
--------------------	------------	--------------------	-----------

NX	M0	Furhman grade III. Extensive chronic pyelonephritis.
NX	M0	Furhman grade III. Extensive chronic pyelonephritis.

Source: NCI Genomic Data Commons file 02946937-7635-4018-a8be-6447ed88fc53 (TCGA-HE-7129.E79F4BA6-265D-4C26-88BE-1651F2448524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).